Surgical pathology report (de-identified scan), TCGA case TCGA-43-8115, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-43-8115-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

Phon [REDACTED]

Final Surgical Pathology Report

Procedure: [REDACTED]

Diagnosis

A. Lung, left lower lobe, excision -
Poorly differentiated squamous cell carcinoma (see microscopic description).
Margins negative for malignancy.
Metastatic carcinoma in three of fourteen (3/14) hilar lymph nodes.

B,C,D. Lymph nodes, level 9, level 7, and level 5, excisions -
Negative for tumor.

Microscopic Description:

Histologic type: Squamous cell carcinoma comprising the mass lesion in part A

Histologic grade: Poorly differentiated

Primary tumor (pT): pT2a. The carcinoma is 3.5 cm in greatest dimension. To the extent assessable given fragmentation, there is not pleural invasion.

Margins of resection: Negative

Direct extension of tumor: Not definitively identified

Vascular invasion: Not identified

Regional lymph nodes (pN): pN1. There is metastatic carcinoma in three of fourteen (3/14) hilar lymph nodes identified in part A. The separately submitted lymph nodes in parts B, C, & D are negative for tumor.

Distant metastasis (pM): Not applicable

Other findings: Scattered chronic inflammation and emphysematous changes

Note: The carcinoma immunostains for p63 and not for TTF-1, nor does it immunostain for synaptophysin or chromogranin. This supports classification of this non-small cell carcinoma as poorly differentiated squamous cell carcinoma.

[A few of the antibodies used in our laboratory may be classified as analyte specific reagents. These antibodies are monitored and controlled in our laboratory and their performance for in vitro diagnosis is well described in the medical literature. They have not been cleared or approved by the FDA.]

Specimen

- A. Left lower lobe
- B. Level 9 lymph node
- C. Level 7 lymph node
- D. Level 5 lymph node

Clinical Information

PRE-OP DIAGNOSIS: Lung cancer

[page 2 of 2]
Gross Description

A. Received fresh in a container labeled "left lower lobe" is a 187 g, 18 x 9.5 x 5 cm, lobectomy specimen. The bronchial stump is 1.5 cm long and without focal lesion. The vascular margin is also grossly unremarkable. The pleural surface is smooth glistening tan-red. There is a torn area on the pleural surface revealing a 3.5 x 3 x 2.5 cm tan-pink mass. Although the prior tearing limits assessment, the mass does not appear to involve the pleura. The lung away from the mass is spongy and tan-pink, without additional lesions. There are gray-black lymph nodes in the hilar region up to 0.8 cm in greatest dimension. RS-12, following fixation, according to the accompanying block summary.

Please note tissue is taken for tissue procurement per the clinical request.

BLOCK SUMMARY: A1 - bronchial margin; A2 - vascular margins; A3 -A7 - lesion, including relationship to disrupted pleura and adjacent parenchyma; A8 - tumor to hilar region, including two intraparenchymal lymph nodes; A9,A10 - lung away from tumor; A11,A12 -lymph nodes, with six lymph nodes per block.

B. Received fresh in a container labeled "level 9 lymph node" is a 0.5 cm soft tan-gray lymph node with a scant amount of associated adipose tissue.

C. Received fresh in a container labeled "level 7 lymph node" are two tan-gray lymph nodes, 0.8 cm and 1.8 cm in greatest dimension.

D. Received fresh in a container labeled "level 5 lymph node" is a 0.5 cm soft gray-black lymph node, with a scant amount of associated adipose tissue.

Source: NCI Genomic Data Commons file 702608c2-ab9b-4cd0-9d48-37e7fd5c9f5f (TCGA-43-8115.A18F4EC6-0500-4E01-98FF-E30FAA481FA4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).